Somatic mutation profile of tumor specimen TCGA-S9-A6WD-01A (aliquot TCGA-S9-A6WD-01A-12D-A33T-08) from TCGA case TCGA-S9-A6WD, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.1 years (21,231 days).
Specimen TCGA-S9-A6WD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3887a094-71b3-4ce4-a09f-880562e8e84d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WD-10A (Blood Derived Normal), aliquot TCGA-S9-A6WD-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a7eb0f8-145d-40da-8e64-9903a9b0c05d

The open-access MAF lists 31 somatic variants for this specimen: 18 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 15, Silent 13, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 84/195 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- C7 | c.1616C>T p.T539M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs761156913, COSV57474096; called by muse, mutect2, varscan2
- CARMIL1 | c.3601A>G p.S1201G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1322359843, COSV100278464; called by muse, mutect2, varscan2
- DDX60 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs754967893, COSV101190566; called by muse, mutect2, varscan2
- EPX | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs200333656, COSV99836678; called by muse, mutect2, varscan2
- GLI2 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as rs531807595, COSV58037437; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLUD1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs777627931, COSV99518331; called by muse, mutect2, varscan2
- IL27RA | c.806G>A p.W269* | Nonsense Mutation (SNP) | VAF 145/388 reads (37%) | catalogued as COSV99652312; called by muse, mutect2, varscan2
- INTS13 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53903939, COSV53904242; called by muse, mutect2, varscan2
- MCCC1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs775931500, COSV99659965; called by muse, mutect2, varscan2
- NR3C1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as COSV51546098, COSV99196515; called by muse, mutect2
- SYNE1 | c.3145A>T p.M1049L (on ENST00000367255 / NM_182961.4; = p.M1056L on NM_033071.3) | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99573455; called by muse, mutect2, varscan2
- TRANK1 | c.4133C>T p.S1378L | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs199834799; called by muse, mutect2, varscan2
- TRIM55 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV99397081; called by muse, mutect2, varscan2
- UBR7 | c.1246_1248del p.R416del | In Frame Del (DEL) | VAF 32/102 reads (31%) | catalogued as rs938250388; called by pindel, varscan2
- ZFP28 | c.2003C>A p.T668K | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100019748; called by muse, mutect2, varscan2
- NEK8 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2
- ZNF292 | c.3460_3463del p.V1154Ifs*7 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | called by pindel, varscan2
- ARHGAP45 | c.2049G>A p.P683= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs199528174, COSV57436270; called by muse, mutect2, varscan2
- CABS1 | c.408C>G p.S136= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV99909022, COSV99909126; called by muse, mutect2, varscan2
- CACUL1 | c.930A>G p.P310= | Silent (SNP) | VAF 124/346 reads (36%) | catalogued as COSV100432633; called by muse, mutect2, varscan2
- COG4 | c.570A>G p.K190= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100092082; called by muse, mutect2, varscan2
- CYP11A1 | c.432G>A p.S144= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs767957985, COSV51435724; called by muse, mutect2, varscan2
- FOXR2 | c.933T>C p.L311= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100189571; called by muse, mutect2, varscan2
- GSG1L | c.612C>T p.L204= (on ENST00000447459 / NM_001109763.2; = p.L49= on NM_144675.2) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs774836604, COSV66576791, COSV66579869; called by muse, mutect2, varscan2
- HSPA13 | c.483A>G p.A161= | Silent (SNP) | VAF 89/205 reads (43%) | catalogued as rs779884462, COSV99580194; called by muse, mutect2, varscan2
- IRS1 | c.906A>C p.R302= | Silent (SNP) | VAF 33/214 reads (15%) | catalogued as COSV100524796; called by muse, mutect2, varscan2
- MPG | c.762G>A p.P254= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs140510538; called by muse, mutect2, varscan2
- PTPRJ | c.1018C>A p.R340= | Silent (SNP) | VAF 56/235 reads (24%) | catalogued as COSV69251840; called by muse, mutect2, varscan2
- ST8SIA4 | c.352C>T p.L118= | Silent (SNP) | VAF 66/298 reads (22%) | catalogued as COSV99185414; called by muse, mutect2, varscan2
- TMEM72 | c.525C>G p.L175= | Silent (SNP) | VAF 156/394 reads (40%) | catalogued as COSV101273556; called by muse, mutect2, varscan2
